Gene-level copy-number profile of tumor specimen C3L-04391-02 from CPTAC case C3L-04391, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,641 days).
Specimen C3L-04391-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5453cd3f-fb98-4b91-9bf9-c69729e64299.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04391-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/23daf9db-3e0e-44a8-ac4a-6e20fb870b2e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,640; copy number 2: 37,480; copy number 3: 11,490; copy number 4: 3,394; copy number 5: 1,294; copy number 6: 247; copy number 7: 93; copy number 8: 100; copy number 10: 27; copy number 12: 148; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,906,673–75,031,528, 2 genes (within-gene range 0–2): SPDYE12P, CASTOR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,905 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:7,141,227–28,338,901, 372 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:28,307,063–28,310,560, 1 gene, copy number 5 (within-gene range 4–5): AC093690.1.
- chr2:176,830,839–182,523,192, 93 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:242,175,181–242,175,634, 1 gene, copy number 15: RPL23AP88.
- chr3:162,486,541–175,810,548, 150 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:175,473,919–187,297,933, 249 genes, copy number 6–12 (broad region; genes not listed).
- chr5:58,198–2,835,139, 82 genes, copy number 5 (broad region; genes not listed).
- chr5:6,839,460–7,219,291, 1 gene, copy number 5 (within-gene range 4–5): LINC02196.
- chr5:7,047,227–37,085,852, 414 genes, copy number 5 (broad region; genes not listed).
- chr7:52,891,837–56,229,782, 71 genes, copy number 7–10 (broad region; genes not listed).
- chr7:64,666,083–64,769,101, 5 genes, copy number 5: ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3.
- chr8:49,330,210–52,460,959, 29 genes, copy number 5–8: RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17.
- chr11:76,591,023–78,215,232, 49 genes, copy number 7: AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35.
- chr16:64,735,925–76,262,365, 388 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,265. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
